Gene-level copy-number profile of tumor specimen TCGA-D7-8572-01A from TCGA case TCGA-D7-8572, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.1 years (20,870 days).
Specimen TCGA-D7-8572-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.dec6ccf4-358e-4827-91b8-1b5b389c41cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8572-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/435ace3a-6198-4e52-8483-f01aea444b94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 3,204; copy number 2: 55,689; copy number 3: 909.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8572-01A-11D-2338-01): tumor purity 0.43, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–5,668,295, 17 genes: EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646, AJAP1, Z98886.1, BX005132.1, LINC02781, LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2, AL365255.1, Z97988.1.
- chr5:166,382,305–166,382,599, 1 gene: AC026403.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
